Somatic mutation profile of tumor specimen MP2PRT-PAWAUS-TMP1-A (aliquot MP2PRT-PAWAUS-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAWAUS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,090 days).
Specimen MP2PRT-PAWAUS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff1d5de6-2b45-452e-bd4e-65ec604b0a8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAUS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAUS-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/570429ae-ad4a-4e98-97de-0deef12e0ea4

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 110/232 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AKR1D1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs1312405780, COSV54336902, COSV54339308; called by muse, mutect2, varscan2
- ANKRD24 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 58/746 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.12); catalogued as rs779927655; called by muse, mutect2
- CDH12 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV66420359; called by muse, mutect2
- DCLK1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366698690, COSV55170182; called by muse, mutect2, varscan2
- DUSP13 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 92/558 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); catalogued as rs937433669; called by muse, mutect2, varscan2
- FBN2 | c.6629G>A p.R2210H | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs745396297, COSV52533552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR85 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51783148; called by muse, mutect2, varscan2
- HSF2BP | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759792745, COSV52360318; called by muse, mutect2
- KALRN | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV53769134; called by muse, mutect2
- LUM | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs912133731, COSV99898899; called by muse, mutect2, varscan2
- PPP2R2B | c.940C>T p.R314C (on ENST00000394409; = p.R380C on NM_181674.2) | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs768002675, COSV60765065; called by muse, mutect2, varscan2
- SH2B2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 42/626 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV60825584; called by muse, mutect2
- SNED1 | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774223730, COSV60024174; called by muse, mutect2, varscan2
- AC007040.2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ACMSD | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- DMBT1 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 142/816 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DUOX2 | c.2594C>G p.T865S | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.017); called by muse, mutect2
- NBEA | c.8008G>T p.D2670Y | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2
- PCDHB3 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMIM30 | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ZMYM2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 22/324 reads (7%) | called by muse, mutect2
- COL24A1 | c.3598C>T p.L1200= | Silent (SNP) | VAF 31/397 reads (8%) | called by muse, mutect2
- CSMD1 | c.6615C>T p.D2205= (on ENST00000520002; = p.D2204= on NM_033225.6) | Silent (SNP) | VAF 51/258 reads (20%) | catalogued as rs1267338247; called by muse, mutect2, varscan2
- FAT1 | c.11028C>T p.N3676= | Silent (SNP) | VAF 84/500 reads (17%) | catalogued as rs1033987682, COSV101499107; called by muse, mutect2, varscan2
- GLP1R | c.807C>T p.Y269= | Silent (SNP) | VAF 102/351 reads (29%) | catalogued as rs201312953; called by muse, mutect2, varscan2
- KAT7 | c.504T>C p.H168= | Silent (SNP) | VAF 23/447 reads (5%) | called by muse, mutect2
- RASD2 | c.411C>T p.I137= | Silent (SNP) | VAF 165/426 reads (39%) | catalogued as COSV53353139; called by muse, mutect2, varscan2
- ZNF281 | c.618C>T p.H206= | Silent (SNP) | VAF 115/410 reads (28%) | called by muse, mutect2, varscan2
- PGA5 | c.657-41C>T | Intron (SNP) | VAF 99/936 reads (11%) | catalogued as rs750801876; called by muse, mutect2, varscan2
- RGS4 | c.-82G>T | 5'UTR (SNP) | VAF 122/327 reads (37%) | called by muse, mutect2, varscan2
